Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A73E, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A73E-01A (Primary Tumor).

Male

DIAGNOSIS:

A. Liver, portion of segment V, subsegmental resection:
Hepatocellular carcinoma, well-differentiated, 5.3 cm in greatest dimension. Resection margin negative for tumor (tumor free margin, 0.3 cm). Vascular invasion is absent.

AJCC stage (with available surgical material): pT1 (7th edition).

This final pathology report is based on the gross/macroscopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

Interpreted by:
Report electronically signed by
Transcribed by:

ADDENDUM:

The background liver parenchyma shows marked steatosis and zone 3 congestion. A trichrome stain shows no significant fibrosis. A PAS-D stain shows no cytoplasmic globules within hepatocytes. An iron stain is negative.

ICD O-3
ICD O-3
Carcinoma, hepatocellular
8/17/13
Site: Liver 22.0
p. 18/1

SHIPAA Discrepancy		☒

Source: NCI Genomic Data Commons file 7afa934a-6bfc-477b-b74b-b1966bf4b876 (TCGA-DD-A73E.10881D8D-1C62-4F3D-ACF6-36AD1F23B0A9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).